Somatic mutation profile of tumor specimen TCGA-CS-4943-01A (aliquot TCGA-CS-4943-01A-01D-1468-08) from TCGA case TCGA-CS-4943, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 37.1 years (13,565 days).
Specimen TCGA-CS-4943-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f16d6557-e3ff-483b-882a-24e4712b81f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-4943-10A (Blood Derived Normal), aliquot TCGA-CS-4943-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1035c09c-6686-4572-b85c-085668b8d5ba

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, RNA 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs763804037, CM970251, COSV100446243, COSV58683273, COSV58688196; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 45/99 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 51/59 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.6281C>G p.S2094* | Nonsense Mutation (SNP) | VAF 81/94 reads (86%) | catalogued as COSV64883331; called by muse, mutect2, varscan2
- C2CD3 | c.1465G>C p.V489L | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV58100928; called by muse, mutect2, varscan2
- CDRT1 | c.1895G>A p.C632Y | Missense Mutation (SNP) | VAF 17/369 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100599997; called by muse, mutect2
- CP | c.274T>C p.F92L | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.324); catalogued as COSV52834059; called by muse, mutect2
- DDX5 | c.1134A>C p.Q378H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.159); catalogued as COSV56751289; called by muse, mutect2, varscan2
- DOC2A | c.619_621del p.K207del | In Frame Del (DEL) | VAF 41/107 reads (38%) | catalogued as rs1051175353; called by pindel, varscan2
- EIF3B | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs368514580; called by muse, mutect2, varscan2
- FBXO7 | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs753951774, COSV56681411; called by muse, mutect2, varscan2
- GFPT2 | c.1394T>A p.I465N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53812486; called by muse, mutect2
- NKAIN2 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.737); catalogued as COSV63689209; called by muse, mutect2, varscan2
- PLCG2 | c.3016G>A p.G1006S | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63876303; called by muse, varscan2
- ROCK2 | c.1619T>A p.L540H | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55084620; called by muse, mutect2, varscan2
- RSBN1 | c.1739G>C p.R580T | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54735250; called by muse, mutect2, varscan2
- RSPH14 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.095); catalogued as rs1243181000, COSV53272147; called by muse, mutect2, varscan2
- RYR1 | c.14468C>T p.T4823M | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs148540135, CM083554; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.14545G>T p.V4849F | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM021677, COSV62110654; called by muse, mutect2, varscan2
- TBC1D4 | c.3110A>T p.D1037V | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV66492225; called by muse, mutect2
- USP25 | c.2579A>G p.N860S | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV53490432; called by muse, mutect2, varscan2
- ALS2 | c.2088C>T p.H696= | Silent (SNP) | VAF 32/68 reads (47%) | catalogued as rs762894364, COSV51892570; called by muse, mutect2, varscan2
- CALCRL | c.717A>C p.T239= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV66477463; called by muse, mutect2, varscan2
- GBP1 | c.1620C>G p.V540= | Silent (SNP) | VAF 87/375 reads (23%) | catalogued as COSV65082956, COSV65084525; called by muse, mutect2, varscan2
- HOXC13 | c.786G>A p.K262= | Silent (SNP) | VAF 95/259 reads (37%) | catalogued as rs755605936, COSV54498310, COSV54499967; ClinVar: likely benign; called by muse, mutect2, varscan2
- LIMS2 | c.654C>T p.H218= (on ENST00000355119 / NM_001161403.3; = p.H242= on NM_017980.4) | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs745965497, COSV55756836; called by muse, mutect2, varscan2
- LVRN | c.2541T>C p.T847= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV63498373; called by muse, mutect2
- NUP214 | c.4332A>G p.Q1444= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV63913162; called by muse, mutect2, varscan2
- ROS1 | c.6987T>C p.P2329= | Silent (SNP) | VAF 46/119 reads (39%) | catalogued as COSV63861639; called by muse, mutect2, varscan2
- SNORD114-14 | n.8A>G | RNA (SNP) | VAF 17/48 reads (35%) | catalogued as rs778540067; called by muse, mutect2, varscan2
